Somatic mutation profile of tumor specimen TCGA-AA-3851-01A (aliquot TCGA-AA-3851-01A-01W-0995-10) from TCGA case TCGA-AA-3851, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 74.2 years (27,090 days).
Specimen TCGA-AA-3851-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c44a373e-d6ab-4db7-aad3-d881802e9dfc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3851-10A (Blood Derived Normal), aliquot TCGA-AA-3851-10A-01W-0995-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/097f4a8d-1ac0-41d0-8132-df2a967fbd2f

The open-access MAF lists 100 somatic variants for this specimen: 73 protein-altering or splice-affecting, 26 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 26, Nonsense Mutation 7, Frame Shift Del 4, Frame Shift Ins 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 24/36 reads (67%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 20/51 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 49/79 reads (62%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS18 | c.3187G>A p.E1063K | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.903); catalogued as rs765403489, COSV99272446; called by muse, mutect2, varscan2
- ADGRD1 | c.1616G>A p.C539Y | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99895286; called by muse, mutect2, varscan2
- ADI1 | c.425A>G p.Y142C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59377344; called by muse, mutect2
- AFF2 | c.2295C>A p.S765R | Missense Mutation (SNP) | VAF 67/90 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV53998272; called by muse, mutect2, varscan2
- ANK1 | c.1228G>A p.V410M | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs1266498510, COSV99225120; called by muse, mutect2, varscan2
- ATP10A | c.2725G>A p.D909N | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as rs202137938, COSV100791177; called by muse, mutect2, varscan2
- CCER1 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100727027; called by muse, mutect2, varscan2
- CENPJ | c.2717del p.L906* | Frame Shift Del (DEL) | VAF 497/1289 reads (39%) | catalogued as rs1431702762; called by mutect2, pindel, varscan2
- CHD4 | c.3274C>T p.R1092W (on ENST00000357008 / NM_001363606.2; = p.R1105W on NM_001273.5) | Missense Mutation (SNP) | VAF 147/362 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58898720; called by muse, mutect2, varscan2
- CMYA5 | c.8299T>C p.S2767P | Missense Mutation (SNP) | VAF 64/113 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV101484088, COSV71407668; called by muse, mutect2, varscan2
- CNOT8 | c.508A>G p.T170A | Missense Mutation (SNP) | VAF 1348/2234 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as COSV99597178; called by mutect2, varscan2
- CNTNAP2 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 79/302 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV100666267; called by muse, mutect2, varscan2
- CSMD1 | c.2654G>A p.R885H (on ENST00000520002; = p.R884H on NM_033225.6) | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771698528, COSV59320511; called by muse, mutect2, varscan2
- DNAJB8 | c.664G>A p.G222S | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs529782278, COSV59879159; called by muse, mutect2, varscan2
- EBF2 | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 63/213 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746363034, COSV68779176; called by muse, mutect2, varscan2
- EFNB3 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 73/123 reads (59%) | catalogued as COSV99872709; called by muse, mutect2, varscan2
- ENC1 | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV56630466; called by muse, mutect2, varscan2
- FAT4 | c.6674A>C p.Y2225S | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs188934368, COSV100628510, COSV58715103; called by muse, mutect2, varscan2
- FERMT2 | c.1316T>G p.F439C | Missense Mutation (SNP) | VAF 86/222 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58408274; called by muse, mutect2, varscan2
- FRY | c.7251_7252insG p.F2418Vfs*11 | Frame Shift Ins (INS) | VAF 12/85 reads (14%) | catalogued as COSV100969202; called by mutect2, pindel, varscan2
- GCK | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs886042610, CM012120, CM096845, COSV60786052; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- GOLGA5 | c.343A>C p.K115Q | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99370916; called by muse, mutect2, varscan2
- GRIA4 | c.674T>C p.I225T | Missense Mutation (SNP) | VAF 96/289 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV99231222; called by muse, mutect2, varscan2
- GUCY1A1 | c.1649C>T p.A550V | Missense Mutation (SNP) | VAF 76/598 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs192008544, COSV56652544; called by muse, varscan2
- IFRD1 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 127/248 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV99133878; called by muse, mutect2, varscan2
- IRF4 | c.103G>A p.G35S | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.095); catalogued as COSV101110959, COSV66705703; called by muse, mutect2, varscan2
- KHSRP | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.034); catalogued as rs758290639, COSV101231174, COSV67919792; called by muse, mutect2, varscan2
- KLK15 | c.467G>T p.S156I | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV100032715, COSV56825806; called by muse, mutect2, varscan2
- LONRF1 | c.1831A>G p.S611G | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.102); catalogued as COSV68037884; called by muse, mutect2, varscan2
- LRMDA | c.494C>G p.S165C | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as COSV65278703; called by muse, mutect2, varscan2
- MDGA2 | c.2153G>A p.R718H (on ENST00000399232 / NM_001113498.2; = p.R420H on NM_182830.4) | Missense Mutation (SNP) | VAF 65/329 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.169); catalogued as rs1470870998, COSV62103795; called by muse, mutect2, varscan2
- MPPED2 | c.436C>A p.P146T | Missense Mutation (SNP) | VAF 363/891 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.165); catalogued as rs747491066, COSV63899854; called by muse, mutect2, varscan2
- MYPN | c.3818C>T p.P1273L | Missense Mutation (SNP) | VAF 138/383 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs148942084; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLGN3 | c.2390G>A p.R797Q (on ENST00000358741 / NM_181303.2; = p.R777Q on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/80 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs139671086, COSV62444470; called by muse, mutect2, varscan2
- NRXN3 | c.2174C>T p.T725M (on ENST00000335750 / NM_001330195.2; = p.T352M on NM_004796.6) | Missense Mutation (SNP) | VAF 102/268 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1404679790, COSV59735686, COSV59774691; called by muse, mutect2, varscan2
- OR14C36 | c.802C>A p.Q268K | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV100507506; called by muse, mutect2, varscan2
- OR5AS1 | c.733C>G p.L245V | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV100546261; called by muse, mutect2, varscan2
- PCDHGA5 | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53960525, COSV53988506; called by muse, mutect2, varscan2
- PIK3R4 | c.2523T>G p.D841E | Missense Mutation (SNP) | VAF 155/670 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63242462; called by muse, mutect2, varscan2
- PINX1 | c.551A>C p.K184T | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as COSV59110041; called by muse, mutect2, varscan2
- PLXNA4 | c.4738C>T p.R1580* | Nonsense Mutation (SNP) | VAF 175/876 reads (20%) | catalogued as rs1416708653, COSV58143767; called by muse, mutect2, varscan2
- PRAMEF1 | c.158C>T p.T53M | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs267597970, COSV60019819; called by muse, mutect2, varscan2
- PRKN | c.561A>C p.L187F | Missense Mutation (SNP) | VAF 70/154 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100628946; called by muse, mutect2, varscan2
- PSG8 | c.1147del p.Q383Kfs*27 | Frame Shift Del (DEL) | VAF 185/752 reads (25%) | catalogued as rs780656185; called by mutect2, pindel, varscan2
- RABGAP1 | c.1231G>A p.V411I | Missense Mutation (SNP) | VAF 31/900 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as rs1399583353, COSV101020083; called by muse, mutect2
- RTN1 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs772853362, COSV50720293, COSV50737223; called by muse, mutect2, varscan2
- SEC16A | c.5346G>T p.R1782S | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51534324; called by muse, mutect2, varscan2
- SEPTIN7 | c.92T>G p.V31G | Missense Mutation (SNP) | VAF 103/480 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63255835; called by muse, mutect2, varscan2
- SETD2 | c.7274C>T p.P2425L | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.678); catalogued as COSV100338913; called by muse, mutect2, varscan2
- SLC18A2 | c.213C>G p.I71M | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as COSV100041623; called by muse, mutect2, varscan2
- SOGA3 | c.2528C>T p.A843V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.27); catalogued as rs1158069206, COSV64104892; called by muse, mutect2, varscan2
- SORCS2 | c.3331G>A p.V1111M | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs762210472, COSV61175236; called by muse, mutect2, varscan2
- STC2 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.994); catalogued as rs775448844, COSV99438344; called by muse, mutect2, varscan2
- TESMIN | c.541C>T p.L181F | Missense Mutation (SNP) | VAF 75/304 reads (25%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.564); catalogued as COSV54833894; called by muse, mutect2, varscan2
- TMEM63A | c.1398C>G p.F466L | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100834372; called by muse, mutect2, varscan2
- TRPA1 | c.1512dup p.G505Rfs*7 | Frame Shift Ins (INS) | VAF 66/205 reads (32%) | catalogued as rs770577826; called by mutect2, pindel, varscan2
- WDFY3 | c.7115A>G p.E2372G | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV99883402; called by muse, mutect2, varscan2
- WDFY3 | c.7114G>T p.E2372* | Nonsense Mutation (SNP) | VAF 30/129 reads (23%) | catalogued as COSV55706959, COSV99883404; called by muse, mutect2, varscan2
- WDR17 | c.179C>A p.A60D | Missense Mutation (SNP) | VAF 115/285 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99707537; called by muse, mutect2, varscan2
- WDR31 | c.642A>C p.L214F (on ENST00000374193 / NM_001006615.3; = p.L213F on NM_145241.5) | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV59146936; called by muse, mutect2, varscan2
- WDR33 | c.3430C>T p.R1144* | Nonsense Mutation (SNP) | VAF 83/232 reads (36%) | catalogued as rs1355738492, COSV59248497; called by muse, mutect2, varscan2
- XKR4 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 60/111 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs377335343, COSV100534262; called by muse, mutect2, varscan2
- ZFHX4 | c.8603T>C p.L2868P | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99262390; called by muse, mutect2, varscan2
- ZNF154 | c.1117C>T p.R373* | Nonsense Mutation (SNP) | VAF 136/346 reads (39%) | catalogued as rs779170902, COSV101377484; called by muse, varscan2
- ZNF761 | c.1833T>A p.C611* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as COSV61888916; called by muse, mutect2, varscan2
- ZNF99 | c.2156C>A p.T719N | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.828); catalogued as COSV101233997, COSV68056149; called by muse, mutect2, varscan2
- BRINP3 | c.837del p.W279Cfs*28 | Frame Shift Del (DEL) | VAF 20/89 reads (22%) | called by mutect2, pindel, varscan2
- MAP3K4 | c.479dup p.N160Kfs*27 | Frame Shift Ins (INS) | VAF 24/110 reads (22%) | called by mutect2, varscan2
- NDST2 | c.1148dup p.W384Lfs*23 | Frame Shift Ins (INS) | VAF 22/62 reads (35%) | called by mutect2, pindel, varscan2
- SLC9B1 | c.331del p.I111Ffs*9 | Frame Shift Del (DEL) | VAF 42/128 reads (33%) | called by mutect2, pindel, varscan2
- ABCA12 | c.4329T>C p.G1443= (on ENST00000272895 / NM_173076.3; = p.G1125= on NM_015657.3) | Silent (SNP) | VAF 437/1390 reads (31%) | catalogued as COSV99789787; called by muse, mutect2, varscan2
- ACAD11 | c.1572A>G p.Q524= | Silent (SNP) | VAF 274/606 reads (45%) | catalogued as COSV99391993; called by muse, mutect2, varscan2
- APBA1 | c.66C>T p.N22= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as rs1488919597, COSV55226193; called by muse, mutect2, varscan2
- APC | c.4107C>A p.P1369= | Silent (SNP) | VAF 51/82 reads (62%) | catalogued as COSV57362785, COSV57398385; called by muse, mutect2, varscan2
- CACNA1E | c.2439G>A p.P813= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as rs779571555, COSV62406502; called by muse, mutect2, varscan2
- CCDC150 | c.1929G>A p.A643= | Silent (SNP) | VAF 126/313 reads (40%) | catalogued as rs777193035, COSV55876466, COSV99777309; called by muse, mutect2, varscan2
- DNAH11 | c.11232C>T p.I3744= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as rs201120788, COSV60966907; called by muse, mutect2, varscan2
- EBF1 | c.1482C>T p.A494= | Silent (SNP) | VAF 29/412 reads (7%) | catalogued as rs778335068, COSV58182157; called by muse, mutect2
- ERICH6 | c.243C>G p.V81= | Silent (SNP) | VAF 160/641 reads (25%) | catalogued as COSV55801854; called by muse, varscan2
- FAM187B | c.894C>T p.P298= | Silent (SNP) | VAF 42/110 reads (38%) | catalogued as rs1262418041, COSV61201536; called by muse, mutect2, varscan2
- FAT4 | c.10494A>G p.L3498= | Silent (SNP) | VAF 45/193 reads (23%) | catalogued as COSV58697673; called by muse, mutect2, varscan2
- HCN4 | c.1140G>A p.T380= | Silent (SNP) | VAF 61/145 reads (42%) | catalogued as rs370059727; called by muse, mutect2, varscan2
- MAP1A | c.363C>T p.S121= | Silent (SNP) | VAF 59/137 reads (43%) | catalogued as rs552869456, COSV55809691; called by muse, mutect2, varscan2
- MYO1B | c.924A>G p.E308= | Silent (SNP) | VAF 127/303 reads (42%) | catalogued as COSV58434592; called by muse, mutect2, varscan2
- OR4C15 | c.18A>G p.T6= | Silent (SNP) | VAF 126/581 reads (22%) | catalogued as COSV58954219; called by muse, mutect2, varscan2
- PALB2 | c.3366C>T p.D1122= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as rs373783514; ClinVar: likely benign; called by muse, mutect2, varscan2
- PEX1 | c.3195G>T p.S1065= | Silent (SNP) | VAF 39/164 reads (24%) | catalogued as COSV50405113; called by muse, mutect2, varscan2
- PLS1 | c.957T>C p.I319= | Silent (SNP) | VAF 124/411 reads (30%) | catalogued as COSV61834700; called by muse, mutect2, varscan2
- PMS2 | c.681C>T p.I227= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as rs188813057, COSV56222929; ClinVar: likely benign; called by muse, mutect2, varscan2
- PPP2R2C | c.999C>T p.Y333= | Silent (SNP) | VAF 42/164 reads (26%) | catalogued as rs747462237, COSV59445832; called by muse, mutect2, varscan2
- PRMT9 | c.1191T>A p.I397= | Silent (SNP) | VAF 37/183 reads (20%) | catalogued as rs761185199, COSV59360491; called by muse, mutect2, varscan2
- PTGR1 | c.567C>T p.V189= | Silent (SNP) | VAF 89/365 reads (24%) | catalogued as rs745307158, COSV53029985; called by muse, mutect2, varscan2
- SLITRK4 | c.1761G>A p.P587= | Silent (SNP) | VAF 70/93 reads (75%) | catalogued as rs782747674, COSV62024146; called by muse, mutect2, varscan2
- STAB2 | c.4992C>T p.V1664= | Silent (SNP) | VAF 278/968 reads (29%) | catalogued as rs767571955, COSV101185936; called by muse, mutect2, varscan2
- STRC | c.3762C>T p.N1254= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs751667703, COSV68660098; called by muse, mutect2, varscan2
- TNRC18 | c.5214C>T p.D1738= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs769934376, COSV68163006; called by muse, mutect2, varscan2
- PYGB | c.1828-563A>G | Intron (SNP) | VAF 65/223 reads (29%) | called by muse, mutect2, varscan2
